Somatic mutation profile of tumor specimen MMRF_1912_1_BM_CD138pos (aliquot MMRF_1912_1_BM_CD138pos_T3_KBS5U_L05850) from MMRF case MMRF_1912, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.0 years (21,197 days).
Specimen MMRF_1912_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb7e6e2a-c609-452a-b833-da0309e862c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1912_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1912_1_PB_CD3pos_C4_KBS5U_L05817; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d94122c-5e9a-4db7-87b6-bc752e698668

The open-access MAF lists 810 somatic variants for this specimen: 264 protein-altering or splice-affecting, 96 silent, 450 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 237, Missense Mutation 230, Intron 115, Silent 96, 5'UTR 48, 5'Flank 20, RNA 16, Nonsense Mutation 14, 3'Flank 14, Splice Region 7, Splice Site 6, Translation Start Site 3.

Variants (750 of 810; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC138647.1 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs1449409223; called by muse, mutect2, varscan2
- ADAMTS2 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51083793; called by muse, mutect2, varscan2
- ADGRV1 | c.14852C>T p.S4951F | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1187404598; called by muse, mutect2, varscan2
- ARMC2 | c.892C>A p.H298N | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as rs1008305354; called by muse, mutect2
- ASIC2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs749146881, COSV63293686; called by muse, mutect2, varscan2
- BICD1 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.112); catalogued as rs1176204686; called by muse, mutect2, varscan2
- C1orf167 | c.2155G>C p.E719Q | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (1); catalogued as rs1385146359; called by muse, mutect2, varscan2
- C2orf91 | n.473C>G | Splice Region (SNP) | VAF 28/133 reads (21%) | catalogued as COSV101106428; called by muse, mutect2, varscan2
- CDADC1 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.114); catalogued as rs1397485280; called by muse, mutect2
- CDK5RAP2 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); catalogued as COSV62572368; called by muse, mutect2, varscan2
- CGAS | c.112C>G p.P38A | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs779830325; called by muse, mutect2
- CHD6 | c.6104G>A p.R2035K | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64692768; called by muse, mutect2
- CNOT3 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs909220037, COSV55365606; called by muse, mutect2
- COL4A4 | c.2158C>A p.P720T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV61632717, COSV61637618; called by muse, mutect2
- CRYBG2 | c.4019C>T p.S1340L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57487903; called by muse, mutect2, varscan2
- CYLD | c.2042-1G>T p.X681_splice | Splice Site (SNP) | VAF 7/33 reads (21%) | catalogued as CS154513; called by muse, mutect2, varscan2
- DENND1C | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV57568717; called by muse, mutect2, varscan2
- DHX29 | c.3920G>A p.R1307Q | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.097); catalogued as rs752824993; called by muse, mutect2, varscan2
- DOK3 | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | catalogued as rs748836235; called by muse, mutect2, varscan2
- DPYSL3 | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs751361322, COSV58330391; called by muse, mutect2, varscan2
- EPHX4 | c.540C>G p.I180M | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV64889379; called by muse, mutect2
- ERF | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55896721; called by muse, mutect2
- ETS1 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.129); catalogued as COSV101200344; called by muse, mutect2, varscan2
- ETV5 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV60505274, COSV60505809; called by muse, mutect2
- FBXO41 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as COSV54586684; called by muse, mutect2, varscan2
- FCRL6 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV58941226; called by muse, mutect2
- FIGN | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs576789489, COSV100291917, COSV60764866; called by muse, mutect2, varscan2
- FNDC3B | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated (0.93); PolyPhen benign (0.048); catalogued as rs993970476; called by muse, mutect2, varscan2
- FRMD1 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.776); catalogued as rs752860506; called by muse, mutect2, varscan2
- GALNTL5 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as rs368842809, COSV67180145; called by muse, mutect2, varscan2
- GNG8 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.78); PolyPhen benign (0.059); catalogued as rs532299872; called by muse, mutect2, varscan2
- GRIA2 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 19/233 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52390630; called by muse, mutect2
- GSTO1 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV63846561; called by muse, mutect2, varscan2
- H2BC7 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.03); catalogued as rs1317720040, COSV61911735, COSV61912284; called by muse, mutect2
- HEPHL1 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.047); catalogued as rs1330956914; called by muse, mutect2, varscan2
- HOMEZ | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV62537253; called by muse, mutect2, varscan2
- HOXC9 | c.165C>G p.F55L | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1407570013, COSV57716319; called by muse, mutect2
- HYDIN | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.04); catalogued as rs372727845; called by muse, mutect2, varscan2
- INPPL1 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53354342; called by muse, mutect2, varscan2
- INTS9 | c.1056G>C p.Q352H | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs755712559; called by muse, mutect2, varscan2
- JPT2 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1030958285, COSV50188487, COSV99027989; called by muse, mutect2
- KCNH1 | c.2245G>A p.E749K (on ENST00000271751 / NM_172362.3; = p.E722K on NM_002238.4) | Missense Mutation (SNP) | VAF 5/138 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV55076207, COSV55093144; called by muse, mutect2
- KIF14 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV66264016; called by muse, mutect2
- KIF22 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs773857563; called by muse, mutect2, varscan2
- KLC3 | c.-8-6C>T | Splice Region (SNP) | VAF 7/87 reads (8%) | catalogued as rs1276709925; called by muse, mutect2
- KLC3 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1283840412; called by muse, mutect2
- KMT2C | c.5437C>T p.Q1813* | Nonsense Mutation (SNP) | VAF 7/85 reads (8%) | catalogued as COSV99030598; called by muse, mutect2
- LIN54 | c.1550C>T p.S517L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs776973799; called by muse, mutect2, varscan2
- LRRC47 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); catalogued as rs760459981, COSV65562164, COSV65562861; called by muse, mutect2, varscan2
- MAK | c.1304A>T p.D435V | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV57564560; called by muse, mutect2, varscan2
- MRPL54 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as rs779084462; called by muse, mutect2, varscan2
- MSMO1 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1173063740; called by muse, mutect2
- MYH13 | c.5117C>G p.S1706* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as rs760378346; called by mutect2, varscan2
- NAP1L4 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65881654, COSV65881934; called by muse, mutect2
- NET1 | c.1018G>A p.E340K (on ENST00000355029 / NM_001047160.3; = p.E286K on NM_005863.5) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as rs774324552; called by muse, mutect2, varscan2
- NHSL1 | c.1305G>C p.Q435H | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs1376370268; called by muse, mutect2
- NIN | c.2903G>A p.R968Q | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs570588999; called by muse, mutect2, varscan2
- NMU | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as COSV51702616; called by muse, mutect2, varscan2
- PBX2 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV66708712; called by muse, mutect2, varscan2
- PKHD1L1 | c.5986G>C p.E1996Q | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as COSV99058815; called by muse, mutect2
- PLEKHH1 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs567827304; called by mutect2, varscan2
- PLSCR2 | c.880G>A p.E294K (on ENST00000497985 / NM_001199978.1; = p.E221K on NM_020359.2) | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV60864859; called by muse, mutect2
- POT1 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62931824; called by muse, mutect2
- PPIP5K2 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs782219353; called by muse, mutect2
- PRSS16 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV57916499; called by muse, mutect2
- PTPN6 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV59684388; called by muse, mutect2, varscan2
- RALY | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55780857; called by muse, mutect2
- RFWD3 | c.797C>G p.S266C | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs1184458444, COSV63098989; called by muse, mutect2, varscan2
- RPL8 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs777113990; called by muse, mutect2, varscan2
- SACS | c.6577G>A p.D2193N | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.137); catalogued as rs149278134; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCAP | c.2515G>C p.D839H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.359); catalogued as rs1341551376; called by muse, mutect2, varscan2
- SCN9A | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.16); PolyPhen benign (0.284); catalogued as COSV57606941; called by muse, mutect2, varscan2
- SEBOX | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV52647636; called by muse, mutect2, varscan2
- SETD2 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.469); catalogued as COSV57437148, COSV57449212; called by muse, mutect2, varscan2
- SGCZ | c.446A>T p.Q149L | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV66008038, COSV66034481; called by muse, mutect2
- SGO2 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV100764788; called by muse, mutect2
- SH3PXD2A | c.328dup p.H110Pfs*6 | Frame Shift Ins (INS) | VAF 24/74 reads (32%) | catalogued as rs777796332; called by mutect2, varscan2
- SKAP2 | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV104422320; called by muse, mutect2, varscan2
- SLC25A20 | c.291G>C p.K97N | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59804496, COSV59804591; called by muse, mutect2, varscan2
- SLC2A13 | c.1368G>C p.K456N | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99786345; called by muse, mutect2, varscan2
- SP140 | c.2323G>C p.E775Q | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs1304344903; called by mutect2, varscan2
- SYNE1 | c.4310+7G>C | Splice Region (SNP) | VAF 5/88 reads (6%) | catalogued as rs1564002853; called by muse, mutect2
- TENM2 | c.2380G>A p.E794K (on ENST00000518659 / NM_001122679.2; = p.E562K on NM_001080428.3) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.744); catalogued as rs1259911343; called by muse, mutect2, varscan2
- TRA2A | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 15/208 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV51718131; called by muse, mutect2
- TRPC4AP | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV99327965; called by muse, mutect2, varscan2
- TRPV3 | c.669C>G p.I223M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1404147400; called by muse, mutect2
- UCKL1 | c.657C>T p.L219= | Splice Region (SNP) | VAF 24/68 reads (35%) | catalogued as rs1281917749; called by muse, mutect2, varscan2
- USP49 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as rs548556992, COSV51897822; called by muse, mutect2, varscan2
- UTRN | c.4375C>T p.H1459Y | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.65); catalogued as COSV62350550; called by muse, mutect2
- VPS41 | c.1921G>C p.E641Q | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.191); catalogued as COSV59651873; called by muse, mutect2
- WDR97 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1250878822; called by muse, mutect2
- WWC1 | c.1672G>A p.G558S | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.921); catalogued as rs779026425; called by muse, mutect2
- XYLT1 | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV54475980, COSV54477959; called by muse, mutect2, varscan2
- ZNF281 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs747158613; called by muse, mutect2, varscan2
- ZNF496 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.188); catalogued as rs575003355; called by muse, mutect2, varscan2
- ZSWIM5 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs1239778288; called by mutect2, varscan2
- ABCA6 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.175); called by muse, mutect2
- ADCK2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- AHNAK2 | c.16210G>A p.D5404N | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- AL441992.2 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ANGPT1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF40 | c.2584G>C p.E862Q | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2
- ARPP21 | c.687-1G>T p.X229_splice | Splice Site (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- ARPP21 | c.1086G>A p.W362* | Nonsense Mutation (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- ATG4B | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATL2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); called by muse, varscan2
- ATP6V0A1 | c.682C>A p.Q228K | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- B4GALT2 | c.752C>G p.A251G | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- B4GALT3 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- BBOX1 | c.917G>C p.R306T | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- BPTF | c.8505G>C p.Q2835H | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BYSL | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- CACNA1D | c.3266C>G p.S1089C (on ENST00000350061 / NM_001128840.3; = p.S1109C on NM_000720.4) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- CARF | c.1379G>C p.R460T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCDC3 | c.729G>C p.Q243H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDKN1C | c.794A>G p.K265R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.379); called by muse, mutect2
- CDKN1C | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPU | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CEP97 | c.1202C>T p.S401L | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, varscan2
- CFAP44 | c.1143C>G p.I381M | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- CFAP92 | c.2522C>T p.S841F | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- CFP | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CHD7 | c.2305G>A p.D769N | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CIZ1 | c.2148G>A p.L716= | Splice Region (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- CLEC16A | c.2845C>A p.P949T | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.043); called by muse, mutect2
- CLUAP1 | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COQ5 | c.399G>C p.Q133H | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.447); called by muse, mutect2
- CRLF3 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CUL9 | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2
- DCAF13 | c.1025G>A p.C342Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- DCAF8L2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.311); called by mutect2, varscan2
- DMD | c.8476G>A p.D2826N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- DNAH14 | c.2796G>C p.L932F (on ENST00000445597; = p.L998F on NM_001367479.1) | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by mutect2, varscan2
- DOCK10 | c.5416G>C p.E1806Q | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- DOCK10 | c.1298G>A p.R433K | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- DST | c.11732C>T p.S3911L (on ENST00000361203 / NM_001374722.1; = p.S1499L on NM_015548.5) | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DTWD2 | c.763C>G p.Q255E | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- EBNA1BP2 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EME2 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- EPB41L5 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- EPG5 | c.3532C>T p.Q1178* | Nonsense Mutation (SNP) | VAF 19/32 reads (59%) | called by muse, mutect2, varscan2
- FAM228B | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 4/91 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.604); called by muse, mutect2
- FASTKD2 | c.1575C>G p.I525M | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- FAT3 | c.11857G>A p.E3953K | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- FBN2 | c.1330C>A p.P444T | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FMO2 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- FREM2 | c.5642-1G>C p.X1881_splice | Splice Site (SNP) | VAF 10/14 reads (71%) | called by muse, mutect2
- FTL | c.114C>A p.F38L | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- FZD10 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- G3BP2 | c.1021G>C p.D341H | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- GCN1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2
- GMCL1 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | called by muse, mutect2, varscan2
- GOLGA2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GPR19 | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- GRK4 | c.1411C>T p.H471Y (on ENST00000398052 / NM_182982.3; = p.H439Y on NM_005307.3) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- HAUS5 | c.589C>G p.Q197E | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- HCFC2 | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- HECTD4 | c.3389G>A p.G1130E | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HECW1 | c.3422G>C p.R1141T | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.168); called by muse, mutect2
- HELZ2 | c.4003G>C p.E1335Q (on ENST00000467148 / NM_001037335.2; = p.E766Q on NM_033405.3) | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.238); called by muse, mutect2
- IGHV2-70D | c.175C>A p.R59S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, varscan2
- IGLV3-10 | c.47-2A>T p.X16_splice | Splice Site (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- IKBKB | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.392); called by muse, mutect2
- IRF1 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- ITGA8 | c.66C>A p.C22* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- ITGAM | c.2169C>G p.I723M (on ENST00000648685 / NM_001145808.2; = p.I722M on NM_000632.4) | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- KDELR3 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- KIAA0232 | c.437-1G>A p.X146_splice | Splice Site (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- KIAA1217 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- KLF13 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- KRT33A | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 7/114 reads (6%) | called by muse, mutect2
- LCTL | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 21/64 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- LINC00583 | n.171C>T | Splice Region (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- LRRC14 | c.856C>G p.L286V | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LSM11 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- LYAR | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.137); called by muse, mutect2
- MAP1A | c.4901G>C p.R1634T | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2
- METTL3 | c.202_218del p.A68Yfs*4 | Frame Shift Del (DEL) | VAF 21/75 reads (28%) | called by mutect2, varscan2
- MMS22L | c.1657G>C p.D553H | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- MPDZ | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- MROH2B | c.2869C>G p.L957V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MST1 | c.691C>T p.L231F | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MTCL1 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- MYH3 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); called by muse, mutect2
- MYLK4 | c.-111C>G | Splice Region (SNP) | VAF 9/136 reads (7%) | called by muse, mutect2
- MYO10 | c.4750G>A p.D1584N | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MYO16 | c.4834G>A p.E1612K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by mutect2, varscan2
- MYOM3 | c.2155G>C p.G719R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NBEAL2 | c.7189C>T p.H2397Y | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- NCL | c.921C>G p.F307L | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.063); called by muse, mutect2
- NEDD1 | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- NFKBIZ | c.479C>A p.S160* | Nonsense Mutation (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- NLE1 | c.99C>A p.F33L | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NRG3 | c.1074A>T p.Q358H | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- OPN3 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTX1 | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OVCA2 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 7/185 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.03); called by muse, mutect2
- PAXIP1 | c.1786C>T p.P596S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PIK3C2B | c.3925G>C p.E1309Q | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- PIK3C2B | c.1330C>T p.H444Y | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.996); called by muse, mutect2
- PLCE1 | c.1538C>T p.S513L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PLEKHG3 | c.577G>C p.E193Q (on ENST00000394691; = p.E249Q on NM_001308147.2) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.067); called by muse, mutect2
- PLEKHG4 | c.1666G>C p.E556Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PPARG | c.804G>C p.K268N (on ENST00000287820 / NM_015869.5; = p.K238N on NM_005037.7) | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- PPFIA3 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PRKG1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRSS2 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAPGEFL1 | c.1707G>T p.K569N | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.466); called by muse, mutect2
- RCC2 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- RIC8B | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ROBO3 | c.2226C>G p.I742M | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ROS1 | c.5486G>C p.R1829T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- SACS | c.3411G>C p.K1137N | Missense Mutation (SNP) | VAF 73/100 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SALL3 | c.2562G>A p.M854I | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SCARF2 | c.2527del p.R843Gfs*101 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by mutect2, varscan2
- SCN9A | c.5803G>A p.D1935N (on ENST00000303354; = p.D1924N on NM_002977.3) | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SGMS1 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- SHOC1 | c.3973C>T p.Q1325* | Nonsense Mutation (SNP) | VAF 44/130 reads (34%) | called by muse, mutect2, varscan2
- SLC22A11 | c.1215G>T p.Q405H | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SLC2A11 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 29/131 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC46A3 | c.682C>G p.Q228E | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- SLC47A1 | c.1287dup p.A430Cfs*70 | Frame Shift Ins (INS) | VAF 16/58 reads (28%) | called by pindel, varscan2
- SLC52A1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.022); called by muse, mutect2
- SLC8A1 | c.1843G>C p.E615Q | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCA5 | c.2878C>T p.H960Y | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SMG1 | c.4738G>A p.E1580K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.89); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SNX17 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- SOS2 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SPOPL | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- SPTA1 | c.4657G>A p.E1553K | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.278); called by muse, mutect2
- SQLE | c.933G>A p.M311I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- SRGAP1 | c.1625G>C p.R542T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SZT2 | c.1096C>G p.Q366E | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.084); called by muse, mutect2
- TCF3 | c.1913C>T p.S638L | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.261); called by muse, mutect2
- TCHHL1 | c.1942G>C p.E648Q | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.063); called by muse, mutect2
- TDRD5 | c.2519C>T p.S840F | Missense Mutation (SNP) | VAF 7/192 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2
- TLN1 | c.4812G>C p.K1604N | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- TM9SF2 | c.1105C>G p.L369V | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.023); called by muse, mutect2
- TMED8 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.063); called by muse, mutect2
- TPBGL | c.1130C>A p.S377Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- TRAF1 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- TRAF6 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.168); called by mutect2, varscan2
- TRAPPC4 | c.558C>G p.F186L | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM25 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TRIM51GP | c.1110G>A p.M370I | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- TRPC3 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRPM3 | c.2668C>T p.L890F (on ENST00000357533 / NM_001366142.2; = p.L733F on NM_020952.6) | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- TTC21A | c.3291G>C p.K1097N | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.109); called by muse, mutect2
- TTK | c.1990G>T p.D664Y | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBE3B | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.143); called by muse, mutect2
- UBE4A | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.029); called by muse, mutect2
- UBR4 | c.13877G>C p.G4626A | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- UMODL1 | c.2834C>T p.S945F (on ENST00000408910 / NM_001004416.2; = p.S1073F on NM_173568.3) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- UNC5B | c.16G>T p.G6* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | called by mutect2, varscan2
- VWA5B2 | c.3403G>A p.E1135K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.94); called by muse, varscan2
- WNK1 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- XPA | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZBTB47 | c.33G>T p.Q11H | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZC3H7B | c.2518-1G>C p.X840_splice | Splice Site (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- ZNF131 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF280B | c.935G>A p.C312Y | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF354B | c.1431G>C p.Q477H | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.913); called by mutect2, varscan2
- ZNF571 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ZNF747 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- ACOX2 | c.1260G>T p.L420= | Silent (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2
- AKT1S1 | c.654C>T p.I218= (on ENST00000344175 / NM_001098633.4; = p.I238= on NM_032375.5) | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs766848323, COSV59273976; called by muse, mutect2, varscan2
- ANKMY1 | c.348C>T p.L116= | Silent (SNP) | VAF 23/80 reads (29%) | called by muse, mutect2, varscan2
- ARL16 | c.411C>G p.L137= | Silent (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- ATG2B | c.5589C>T p.G1863= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs748724343; called by muse, mutect2, varscan2
- ATP1A3 | c.1737G>A p.V579= (on ENST00000545399 / NM_001256214.2; = p.V566= on NM_152296.5) | Silent (SNP) | VAF 35/105 reads (33%) | called by muse, mutect2, varscan2
- AUTS2 | c.2205C>T p.L735= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs1301078103; called by muse, mutect2, varscan2
- B4GALNT3 | c.60G>A p.R20= | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- BBC3 | c.390C>T p.L130= (on ENST00000449228 / NM_001127240.3; = p.S96L on NM_014417.5) | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs747413729; called by muse, mutect2, varscan2
- BBOF1 | c.438G>A p.L146= | Silent (SNP) | VAF 14/124 reads (11%) | called by muse, mutect2, varscan2
- BHMT2 | c.129C>G p.L43= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV54873810; called by muse, mutect2, varscan2
- BICRAL | c.2784G>A p.L928= | Silent (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- BTBD9 | c.1554C>T p.V518= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- C12orf57 | c.180G>A p.Q60= | Silent (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- CACNG6 | c.195C>T p.L65= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs769787760; called by muse, mutect2, varscan2
- CENPF | c.1143C>T p.A381= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs1173255326; called by muse, mutect2, varscan2
- CLDN3 | c.534G>A p.A178= | Silent (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- CLTB | c.132C>T p.F44= | Silent (SNP) | VAF 37/83 reads (45%) | called by muse, mutect2, varscan2
- CNBD1 | c.471G>A p.L157= | Silent (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- CRB2 | c.1245C>T p.F415= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as rs770973228; called by muse, mutect2, varscan2
- CYP27C1 | c.255C>T p.I85= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as rs146690447; called by muse, mutect2, varscan2
- DAGLB | c.1461C>T p.I487= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs758391168; called by muse, mutect2, varscan2
- DDX23 | c.1689C>T p.V563= | Silent (SNP) | VAF 41/90 reads (46%) | called by muse, mutect2, varscan2
- DENND5A | c.744C>G p.L248= | Silent (SNP) | VAF 29/91 reads (32%) | called by muse, mutect2, varscan2
- DNAH3 | c.1887G>A p.L629= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs148819655; called by muse, mutect2, varscan2
- DNAJC30 | c.480G>A p.T160= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as rs782537359; called by muse, mutect2
- EPG5 | c.2481C>A p.I827= | Silent (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
- FBXO39 | c.483C>T p.G161= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs377688513; called by muse, mutect2, varscan2
- GALNT5 | c.939G>A p.K313= | Silent (SNP) | VAF 4/90 reads (4%) | called by muse, mutect2
- GLYCTK | c.1206C>T p.V402= | Silent (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- GPAT2 | c.1296C>G p.L432= | Silent (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- GRIN2B | c.1275G>A p.L425= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs950679024; ClinVar: likely benign; called by muse, mutect2, varscan2
- HEXD | c.1116C>T p.V372= (on ENST00000327949 / NM_001369487.1; = p.S402L on NM_173620.3) | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV60063630; called by muse, mutect2, varscan2
- HOXA11 | c.786C>T p.F262= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- HS1BP3 | c.243G>C p.L81= | Silent (SNP) | VAF 39/111 reads (35%) | called by muse, mutect2, varscan2
- IL6R | c.381C>T p.L127= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV59820004; called by mutect2, varscan2
- INPP5B | c.2937G>A p.K979= (on ENST00000373023; = p.K899= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- KCNJ14 | c.30C>T p.L10= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs928639669, COSV53519720; called by muse, mutect2, varscan2
- KCNQ4 | c.1542G>A p.E514= | Silent (SNP) | VAF 7/188 reads (4%) | called by muse, mutect2
- KDSR | c.702G>A p.E234= | Silent (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
- KHDRBS1 | c.468G>A p.L156= | Silent (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- KLHL6 | c.141C>T p.V47= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as rs1004787604, COSV58069925; called by muse, varscan2
- LCT | c.5580C>T p.I1860= | Silent (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2
- LMAN2L | c.222G>C p.L74= | Silent (SNP) | VAF 5/117 reads (4%) | catalogued as COSV53840559; called by muse, mutect2
- MECR | c.366G>A p.L122= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as rs1372862820; called by muse, mutect2
- MED25 | c.1977G>T p.G659= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- MKRN1 | c.1005G>A p.R335= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs1062773; called by muse, mutect2, varscan2
- MOCS1 | c.1251C>T p.S417= | Silent (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2
- MRC2 | c.3549C>T p.L1183= | Silent (SNP) | VAF 4/67 reads (6%) | called by muse, mutect2
- MUC4 | c.13353C>T p.V4451= (on ENST00000463781 / NM_018406.7; = p.V215= on NM_004532.6) | Silent (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- NAGK | c.78C>T p.I26= | Silent (SNP) | VAF 34/97 reads (35%) | called by muse, mutect2, varscan2
- NDST4 | c.1105C>A p.R369= | Silent (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- NELFCD | c.1485G>A p.V495= (on ENST00000602795; = p.V477= on NM_198976.4) | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs376830862; called by muse, mutect2, varscan2
- NLGN2 | c.1695C>T p.F565= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as rs751321187; called by muse, mutect2, varscan2
- NOX5 | c.861G>A p.L287= | Silent (SNP) | VAF 4/80 reads (5%) | called by muse, mutect2
- NOX5 | c.1689C>A p.I563= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV99534541; called by muse, mutect2, varscan2
- NOXRED1 | c.786G>A p.L262= | Silent (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- NSUN7 | c.1467C>T p.F489= | Silent (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- ORAI1 | c.369C>T p.F123= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as rs782031667; called by muse, mutect2
- PDIA3 | c.21G>A p.A7= | Silent (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- PLCD3 | c.903C>G p.L301= | Silent (SNP) | VAF 11/43 reads (26%) | called by mutect2, varscan2
- POLR2A | c.3624C>T p.S1208= | Silent (SNP) | VAF 12/166 reads (7%) | called by muse, mutect2
- PURG | c.393G>C p.L131= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as COSV53295591, COSV53296220; called by muse, mutect2, varscan2
- RAI1 | c.5334G>C p.R1778= | Silent (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- RARS1 | c.66G>A p.L22= | Silent (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- RARS1 | c.1890G>A p.V630= | Silent (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- RETREG3 | c.225G>A p.L75= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as COSV52220680; called by muse, varscan2
- RNF186 | c.159C>G p.P53= | Silent (SNP) | VAF 28/90 reads (31%) | called by muse, mutect2, varscan2
- SBF1 | c.2091C>G p.L697= | Silent (SNP) | VAF 24/64 reads (38%) | called by muse, varscan2
- SDF4 | c.522C>T p.I174= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV55420785, COSV99027809; called by muse, mutect2, varscan2
- SLC9A9 | c.264C>T p.F88= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV57230334; called by muse, mutect2, varscan2
- SPATA2L | c.504G>A p.V168= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs1339658921; called by muse, mutect2
- SPCS2 | c.522G>C p.L174= | Silent (SNP) | VAF 34/104 reads (33%) | called by muse, mutect2, varscan2
- SPIN1 | c.732C>T p.F244= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs1424727512; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1122G>A p.L374= | Silent (SNP) | VAF 3/51 reads (6%) | catalogued as rs1019605262; called by muse, mutect2
- SYNE1 | c.21540G>A p.L7180= (on ENST00000367255 / NM_182961.4; = p.L7109= on NM_033071.3) | Silent (SNP) | VAF 40/99 reads (40%) | called by muse, mutect2, varscan2
- TBC1D9 | c.3759C>T p.L1253= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV71307368; called by muse, mutect2, varscan2
- TBCEL | c.216C>T p.F72= | Silent (SNP) | VAF 7/183 reads (4%) | called by muse, mutect2
- THSD7B | c.2109C>G p.V703= | Silent (SNP) | VAF 37/83 reads (45%) | called by muse, mutect2, varscan2
- TMC7 | c.2046C>T p.F682= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1195732483, COSV58581655; called by muse, mutect2, varscan2
- TMED9 | c.27C>T p.L9= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs759506866; called by muse, mutect2, varscan2
- TNPO1 | c.2421C>T p.T807= | Silent (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- TPSB2 | c.210G>A p.L70= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs775320822; called by muse, mutect2, varscan2
- TRPC7 | c.118C>T p.L40= | Silent (SNP) | VAF 38/129 reads (29%) | called by mutect2, varscan2
- TRRAP | c.5898G>A p.L1966= (on ENST00000359863 / NM_001244580.1; = p.L1948= on NM_003496.3) | Silent (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2
- UBE2Z | c.612G>A p.Q204= | Silent (SNP) | VAF 41/76 reads (54%) | catalogued as COSV100711560; called by muse, mutect2, varscan2
- USHBP1 | c.561G>C p.L187= | Silent (SNP) | VAF 8/131 reads (6%) | called by muse, mutect2
- USP53 | c.1266C>T p.H422= | Silent (SNP) | VAF 9/60 reads (15%) | called by mutect2, varscan2
- VPS13A | c.3792G>A p.L1264= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs1247441048, COSV62437475; called by muse, mutect2
- VPS37A | c.84G>A p.Q28= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- XPR1 | c.1539G>A p.L513= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as rs750004423, COSV62558470; called by muse, mutect2, varscan2
- ZNF205 | c.972G>A p.V324= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- ZNF592 | c.1006C>T p.L336= | Silent (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- ZNF646 | c.4515C>T p.L1505= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs1311249092; called by muse, mutect2
- ZNF691 | c.282C>G p.V94= (on ENST00000372502; = p.V63= on NM_015911.3) | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV65289738; called by muse, mutect2, varscan2
- ZNF729 | c.327G>A p.L109= | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- ABCA2 | c.768+133C>G | Intron (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- ABRACL | c.61+286T>C | Intron (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- AC009779.3 | c.*1177C>T | 3'UTR (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- AC073578.1 | n.921C>T | RNA (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- AC074085.2 | n.59G>A | RNA (SNP) | VAF 29/86 reads (34%) | catalogued as rs1239477899; called by muse, mutect2, varscan2
- AC118942.1 | n.777C>T | RNA (SNP) | VAF 4/77 reads (5%) | called by muse, mutect2
- ACTL10 | c.-794G>A | 5'UTR (SNP) | VAF 40/96 reads (42%) | called by muse, mutect2, varscan2
- ADAM9 | chr8:38996951 C>T | 5'Flank (SNP) | VAF 13/30 reads (43%) | catalogued as rs1004167249; called by muse, mutect2, varscan2
- ADAM9 | c.2210+67C>T | Intron (SNP) | VAF 10/32 reads (31%) | catalogued as rs1196392530; called by mutect2, varscan2
- ADAMTS13 | c.-19C>T | 5'UTR (SNP) | VAF 23/60 reads (38%) | catalogued as rs782227169, COSV100746907; called by muse, mutect2, varscan2
- ADAR | c.2497-73C>T | Intron (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2
- ADCYAP1 | c.-90C>T | 5'UTR (SNP) | VAF 39/83 reads (47%) | called by muse, mutect2, varscan2
- ADD1 | c.1161+129G>A | Intron (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- ADGRE3 | c.*106G>C | 3'UTR (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- ADTRP | c.*821G>A | 3'UTR (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- AGPAT2 | c.*598C>G | 3'UTR (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- AIF1L | c.*1955G>A | 3'UTR (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- AKAP10 | c.-94C>T | 5'UTR (SNP) | VAF 11/31 reads (35%) | catalogued as rs1436252948; called by muse, mutect2, varscan2
- AL162417.1 | c.397-17010C>G | Intron (SNP) | VAF 31/66 reads (47%) | catalogued as COSV64454486; called by muse, mutect2, varscan2
- AL359195.2 | n.3421C>T | RNA (SNP) | VAF 10/226 reads (4%) | called by muse, mutect2
- ALDH1A3 | c.*1530G>C | 3'UTR (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- AMDHD1 | c.*419T>G | 3'UTR (SNP) | VAF 28/58 reads (48%) | catalogued as rs551075382; called by muse, varscan2
- AMER3 | c.*2499G>A | 3'UTR (SNP) | VAF 6/99 reads (6%) | called by muse, mutect2
- ANK1 | c.126+67754G>A | Intron (SNP) | VAF 30/78 reads (38%) | called by muse, mutect2, varscan2
- ANKRD29 | c.*1950G>C | 3'UTR (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- ANO10 | c.*705G>C | 3'UTR (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- AP3S2 | chr15:89894333 C>T | 5'Flank (SNP) | VAF 39/82 reads (48%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.-334G>A | 5'UTR (SNP) | VAF 14/36 reads (39%) | catalogued as rs1466535811; called by muse, mutect2, varscan2
- ARHGAP5 | c.*3952C>G | 3'UTR (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- ARID2 | chr12:45727455 G>A | 5'Flank (SNP) | VAF 33/105 reads (31%) | called by muse, mutect2, varscan2
- ARMC8 | c.1134+224G>A | Intron (SNP) | VAF 5/113 reads (4%) | called by muse, mutect2
- ARSJ | c.*1819G>A | 3'UTR (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- ASCC1 | c.*531C>G | 3'UTR (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- BACE1 | c.*3738G>T | 3'UTR (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2, varscan2
- BAIAP2 | c.280-115C>T | Intron (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- BBC3 | c.378-253C>T | Intron (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- BDNF | c.*2187G>C | 3'UTR (SNP) | VAF 31/79 reads (39%) | catalogued as rs552619701; called by muse, mutect2, varscan2
- BIRC6 | c.*324_*326del | 3'UTR (DEL) | VAF 5/46 reads (11%) | called by pindel, varscan2
- BRWD1 | c.6572-2980C>A | Intron (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
- BTK | c.*247G>T | 3'UTR (SNP) | VAF 23/29 reads (79%) | catalogued as COSV100437816; called by muse, mutect2, varscan2
- BX119917.1 | n.9C>T | RNA (SNP) | VAF 26/44 reads (59%) | called by muse, mutect2, varscan2
- C10orf53 | c.*985G>C | 3'UTR (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2
- C11orf80 | c.1043-80C>T | Intron (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- C12orf57 | chr12:6944007 C>A | 5'Flank (SNP) | VAF 5/82 reads (6%) | catalogued as rs190605659; called by muse, mutect2
- C1R | c.1080+965G>A | Intron (SNP) | VAF 9/40 reads (23%) | catalogued as rs1018684479; called by muse, mutect2, varscan2
- C2orf16 | c.*73C>T | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- CACNA1D | c.4111-42G>A | Intron (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- CACNA2D2 | c.2936+26G>C | Intron (SNP) | VAF 14/166 reads (8%) | catalogued as COSV99816877; called by muse, mutect2
- CACUL1 | c.*1295C>T | 3'UTR (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- CALHM1 | c.*394C>G | 3'UTR (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- CAMTA2 | c.3262-9C>T | Intron (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- CANT1 | c.*613C>T | 3'UTR (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- CCDC117 | c.-35G>A | 5'UTR (SNP) | VAF 13/35 reads (37%) | catalogued as rs959401370; called by muse, mutect2, varscan2
- CCDC138 | c.-41G>A | 5'UTR (SNP) | VAF 22/45 reads (49%) | catalogued as rs1369738676; called by muse, mutect2, varscan2
- CCDC62 | c.*366G>C | 3'UTR (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2, varscan2
- CCDC71L | c.*1559C>T | 3'UTR (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- CCDC73 | c.429+126C>G | Intron (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- CCNI2 | c.*180C>T | 3'UTR (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- CD164 | c.-61G>A | 5'UTR (SNP) | VAF 5/66 reads (8%) | called by muse, mutect2
- CD46 | c.1027+70G>A | Intron (SNP) | VAF 8/44 reads (18%) | catalogued as rs1308442813; called by muse, mutect2, varscan2
- CD96 | c.*506G>A | 3'UTR (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- CDC42BPA | chr1:227317799 C>T | 5'Flank (SNP) | VAF 5/88 reads (6%) | catalogued as rs1229333621; called by muse, mutect2
- CDK13 | c.1211+81C>T | Intron (SNP) | VAF 12/37 reads (32%) | catalogued as rs1248230192; called by muse, mutect2, varscan2
- CDKN2B | c.*1244G>A | 3'UTR (SNP) | VAF 25/67 reads (37%) | called by muse, mutect2, varscan2
- CDS2 | c.*3026C>T | 3'UTR (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- CDX1 | c.*260C>G | 3'UTR (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- CEBPB | c.*320G>A | 3'UTR (SNP) | VAF 42/104 reads (40%) | catalogued as COSV100269827; called by muse, mutect2, varscan2
- CEP78 | c.*4402G>C | 3'UTR (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- CERK | c.*2370C>T | 3'UTR (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- CFL2 | c.3+23G>A | Intron (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- CHEK1 | c.*27+1658G>A | Intron (SNP) | VAF 5/56 reads (9%) | catalogued as rs936244239; called by muse, mutect2
- CHFR | chr12:132840283 C>T | 3'Flank (SNP) | VAF 10/13 reads (77%) | called by muse, mutect2, varscan2
- CHRNA5 | c.*1520T>C | 3'UTR (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- CHRNB1 | c.-26G>A | 5'UTR (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- CHST3 | c.*3344T>C | 3'UTR (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- CLASP2 | c.862+237C>T | Intron (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- CLEC4G | c.221-35G>A | Intron (SNP) | VAF 13/40 reads (33%) | catalogued as rs1223841681; called by muse, mutect2, varscan2
- CLIC6 | c.*766G>C | 3'UTR (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- CLK1 | c.482-20G>A | Intron (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- CLRN1 | chr3:150926373 C>T | 3'Flank (SNP) | VAF 7/35 reads (20%) | called by mutect2, varscan2
- COBLL1 | c.64+25G>A | Intron (SNP) | VAF 24/30 reads (80%) | called by muse, varscan2
- COPS8 | c.*1966G>A | 3'UTR (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- COX10 | c.*665C>T | 3'UTR (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- CRHR2 | c.90+60C>T | Intron (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- CRYBA2 | c.303+78C>G | Intron (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2
- CSMD1 | c.-298C>T | 5'UTR (SNP) | VAF 4/12 reads (33%) | catalogued as COSV68207843; called by muse, mutect2
- CTCF | c.*1073C>A | 3'UTR (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- CTDSP1 | c.-213C>G | 5'UTR (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- CTNND2 | c.*1477G>C | 3'UTR (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- CTSD | c.*437C>G | 3'UTR (SNP) | VAF 32/76 reads (42%) | catalogued as rs698450; called by muse, mutect2, varscan2
- CTSS | c.*1119C>T | 3'UTR (SNP) | VAF 9/49 reads (18%) | called by mutect2, varscan2
- CUL7 | c.-36C>T | 5'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- CXCR3 | c.*271C>T | 3'UTR (SNP) | VAF 13/17 reads (76%) | called by muse, mutect2, varscan2
- DDX27 | c.1367-154C>G | Intron (SNP) | VAF 7/9 reads (78%) | called by muse, mutect2
- DEPDC5 | c.1666+490C>T | Intron (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- DHDDS | c.*1957C>T | 3'UTR (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- DHFR2 | c.*2584G>T | 3'UTR (SNP) | VAF 9/208 reads (4%) | called by muse, mutect2
- DIS3L | c.2201+23G>A | Intron (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- DRAM1 | c.*1878C>T | 3'UTR (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- DTX2P1 | n.303C>G | RNA (SNP) | VAF 33/86 reads (38%) | catalogued as rs1372146214; called by muse, mutect2, varscan2
- DUSP5 | c.*857C>T | 3'UTR (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
- DVL2 | c.1034+46C>A | Intron (SNP) | VAF 16/34 reads (47%) | called by muse, varscan2
- ECT2L | c.*447G>A | 3'UTR (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- EED | c.-414G>A | 5'UTR (SNP) | VAF 27/79 reads (34%) | called by muse, mutect2, varscan2
- EFCAB2 | c.*2349C>T | 3'UTR (SNP) | VAF 10/122 reads (8%) | catalogued as rs1252269326; called by muse, mutect2
- EHBP1L1 | c.3093+50G>A | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- ELK4 | c.1081-219G>A | Intron (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- ELOVL3 | c.-84C>T | 5'UTR (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- ELOVL6 | c.*1590G>C | 3'UTR (SNP) | VAF 16/50 reads (32%) | called by muse, varscan2
- EMB | c.*2500C>G | 3'UTR (SNP) | VAF 8/199 reads (4%) | called by muse, mutect2
- ENTPD5 | c.*438G>A | 3'UTR (SNP) | VAF 11/15 reads (73%) | called by muse, mutect2, varscan2
- EOLA1 | c.-211+412G>A | Intron (SNP) | VAF 11/12 reads (92%) | catalogued as rs1291044482; called by muse, mutect2, varscan2
- EPAS1 | c.*1308G>C | 3'UTR (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- EPC2 | c.313+1913C>T | Intron (SNP) | VAF 6/107 reads (6%) | called by muse, mutect2
- EPHA10 | c.*2229C>G | 3'UTR (SNP) | VAF 53/113 reads (47%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+7681G>T | Intron (SNP) | VAF 29/83 reads (35%) | called by muse, mutect2, varscan2
- EVL | c.1089-137G>A | Intron (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2
- FAM114A1 | c.*340G>C | 3'UTR (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- FAM114A1 | c.*877G>A | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- FAM118A | c.522+392C>T | Intron (SNP) | VAF 17/39 reads (44%) | catalogued as rs757119767; called by muse, mutect2, varscan2
- FAM133B | c.-91G>A | 5'UTR (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- FAM151B | chr5:80487996 C>T | 5'Flank (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- FAM76B | c.-44C>T | 5'UTR (SNP) | VAF 10/29 reads (34%) | catalogued as rs774626628; called by mutect2, varscan2
- FAM98B | c.*315C>G | 3'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- FBXW7 | c.502-2690G>A | Intron (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- FBXW8 | chr12:117029996 G>T | 3'Flank (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2, varscan2
- FCRL1 | c.*1203C>G | 3'UTR (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- FCRLB | c.*425C>G | 3'UTR (SNP) | VAF 6/113 reads (5%) | called by muse, mutect2
- FEM1C | c.*1888G>A | 3'UTR (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- FER | c.1924+4137G>T | Intron (SNP) | VAF 32/94 reads (34%) | called by muse, mutect2, varscan2
- FGF18 | c.*388G>A | 3'UTR (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- FOXC1 | c.*957C>A | 3'UTR (SNP) | VAF 8/65 reads (12%) | catalogued as rs1029465164; called by muse, mutect2, varscan2
- FRMD3 | c.*1546G>C | 3'UTR (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- FUT2 | chr19:48705684 C>G | 3'Flank (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
- FZD3 | c.*1307G>C | 3'UTR (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- GABRB2 | c.*1949G>A | 3'UTR (SNP) | VAF 29/86 reads (34%) | catalogued as rs1311280506; called by muse, mutect2, varscan2
- GALK2 | c.*1515G>C | 3'UTR (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- GARRE1 | c.-128C>T | 5'UTR (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- GATM | chr15:45378828 G>A | 5'Flank (SNP) | VAF 17/42 reads (40%) | called by muse, varscan2
- GDF15 | c.277+97C>G | Intron (SNP) | VAF 58/116 reads (50%) | called by mutect2, varscan2
- GIGYF1 | c.*87G>C | 3'UTR (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- GIMAP1 | c.*211G>A | 3'UTR (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- GLIPR1 | c.*3529C>T | 3'UTR (SNP) | VAF 14/122 reads (11%) | called by muse, mutect2, varscan2
- GREM2 | c.*1414C>A | 3'UTR (SNP) | VAF 33/101 reads (33%) | called by muse, mutect2, varscan2
- GRIK3 | c.*4766G>A | 3'UTR (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- GRIN2A | c.*5009G>A | 3'UTR (SNP) | VAF 8/48 reads (17%) | called by mutect2, varscan2
- GRIN2C | chr17:74860533 G>A | 5'Flank (SNP) | VAF 16/47 reads (34%) | catalogued as rs775539387; called by muse, mutect2, varscan2
- GRM3 | c.*5G>A | 3'UTR (SNP) | VAF 17/174 reads (10%) | catalogued as COSV100862838; called by muse, mutect2
- GTF2H5 | c.*1538G>C | 3'UTR (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2
- GXYLT1 | c.*1578G>A | 3'UTR (SNP) | VAF 14/42 reads (33%) | catalogued as COSV55142283; called by muse, mutect2, varscan2
- HADHA | c.*213G>C | 3'UTR (SNP) | VAF 12/40 reads (30%) | called by mutect2, varscan2
- HAND1 | c.*421C>G | 3'UTR (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- HCK | c.62+1746G>A | Intron (SNP) | VAF 6/98 reads (6%) | catalogued as rs920780895; called by muse, mutect2
- HCN1 | c.*1882C>G | 3'UTR (SNP) | VAF 36/104 reads (35%) | called by muse, mutect2, varscan2
- HFE | c.*3298G>C | 3'UTR (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- HFE | c.*3702C>G | 3'UTR (SNP) | VAF 32/83 reads (39%) | called by muse, mutect2, varscan2
- HLA-DQB1 | c.*227G>A | 3'UTR (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- HLA-V | n.4195G>A | RNA (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- HOXB3 | chr17:48549787 C>T | 3'Flank (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- HYAL2 | c.-46-526G>A | Intron (SNP) | VAF 30/102 reads (29%) | catalogued as rs940145974; called by muse, mutect2, varscan2
- HYDIN2 | n.842C>T | RNA (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- IAPP | c.80+261G>C | Intron (SNP) | VAF 5/116 reads (4%) | catalogued as rs932545696; called by muse, mutect2
- ICA1L | c.235+23C>G | Intron (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2
- ID1 | c.*86C>T | 3'UTR (SNP) | VAF 16/41 reads (39%) | catalogued as rs1012250246; called by muse, mutect2, varscan2
- ID2 | c.-100G>A | 5'UTR (SNP) | VAF 18/52 reads (35%) | catalogued as COSV99301046, COSV99301128; called by muse, mutect2, varscan2
- IER5L | c.-178G>A | 5'UTR (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- IFFO1 | c.1350+42C>T | Intron (SNP) | VAF 11/44 reads (25%) | catalogued as rs1164118862; called by muse, mutect2
- IGSF11 | c.*1536C>T | 3'UTR (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
- IL6ST | c.*4920C>G | 3'UTR (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- ING5 | c.*93G>A | 3'UTR (SNP) | VAF 10/163 reads (6%) | called by muse, mutect2
- INO80D | c.*5216C>G | 3'UTR (SNP) | VAF 4/92 reads (4%) | called by muse, mutect2
- INSYN2A | c.*1731C>A | 3'UTR (SNP) | VAF 38/95 reads (40%) | called by muse, varscan2
- ITGA3 | c.*1023C>T | 3'UTR (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2, varscan2
- KAT5 | c.592-62G>A | Intron (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- KATNAL2 | c.1211+6930C>T | Intron (SNP) | VAF 4/82 reads (5%) | called by muse, mutect2
- KCNJ13 | c.*1381C>T | 3'UTR (SNP) | VAF 4/59 reads (7%) | called by muse, mutect2
- KCNMA1 | c.*1845C>A | 3'UTR (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- KCNMB4 | c.*3432G>A | 3'UTR (SNP) | VAF 14/135 reads (10%) | called by muse, mutect2, varscan2
- KCNN3 | c.*443C>G | 3'UTR (SNP) | VAF 12/82 reads (15%) | called by mutect2, varscan2
- KCNV1 | chr8:109974984 C>T | 5'Flank (SNP) | VAF 20/74 reads (27%) | called by muse, mutect2, varscan2
- KIAA1549 | c.*5263G>A | 3'UTR (SNP) | VAF 5/63 reads (8%) | called by muse, mutect2
- KIAA1549L | c.*2635C>T | 3'UTR (SNP) | VAF 32/102 reads (31%) | called by muse, mutect2
- KIAA2012 | c.1474+29C>G | Intron (SNP) | VAF 41/105 reads (39%) | catalogued as rs1016056886; called by muse, mutect2, varscan2
- KIF20A | c.*60G>T | 3'UTR (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- KIF26B | c.*87C>T | 3'UTR (SNP) | VAF 16/48 reads (33%) | catalogued as COSV100831820; called by muse, mutect2, varscan2
- KLF9 | c.-1100C>T | 5'UTR (SNP) | VAF 31/77 reads (40%) | called by muse, mutect2, varscan2
- KLHDC10 | c.*200C>G | 3'UTR (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- KLHL22 | c.-33-539C>G | Intron (SNP) | VAF 34/129 reads (26%) | called by muse, mutect2, varscan2
- KRAS | c.*2351C>G | 3'UTR (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- KRT14 | c.*110C>T | 3'UTR (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- KRT15 | chr17:41519878 G>A | 5'Flank (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- KRT73 | c.*243C>G | 3'UTR (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- KRTAP17-1 | c.*293G>T | 3'UTR (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- LARP1 | c.*465C>T | 3'UTR (SNP) | VAF 13/146 reads (9%) | catalogued as rs1177961859; called by muse, mutect2
- LARP6 | c.200+2004G>A | Intron (SNP) | VAF 31/107 reads (29%) | called by muse, mutect2, varscan2
- LBHD1 | c.392-373G>A | Intron (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2, varscan2
- LDAH | c.*436G>C | 3'UTR (SNP) | VAF 7/23 reads (30%) | catalogued as rs1469207686; called by muse, mutect2, varscan2
- LIPI | c.*66C>T | 3'UTR (SNP) | VAF 45/110 reads (41%) | called by muse, mutect2, varscan2
- LMO1 | chr11:8268695 C>T | 5'Flank (SNP) | VAF 5/21 reads (24%) | catalogued as rs1031308629; called by muse, mutect2, varscan2
- LRATD2 | c.*3237G>A | 3'UTR (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- LRCH4 | c.*982G>A | 3'UTR (SNP) | VAF 46/104 reads (44%) | catalogued as rs928081279; called by muse, mutect2, varscan2
- LRRC28 | c.*754G>C | 3'UTR (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- LRRTM4 | c.1551+376G>A | Intron (SNP) | VAF 28/83 reads (34%) | called by muse, varscan2
- LSR | c.*12C>G | 3'UTR (SNP) | VAF 6/99 reads (6%) | catalogued as COSV99723501; called by muse, mutect2
- LUZP2 | c.*3745G>A | 3'UTR (SNP) | VAF 5/98 reads (5%) | called by muse, mutect2
- LYRM9 | c.*104G>A | 3'UTR (SNP) | VAF 5/56 reads (9%) | catalogued as rs1239222395; called by muse, mutect2
- MALT1 | c.*3130C>T | 3'UTR (SNP) | VAF 13/45 reads (29%) | catalogued as rs1450119255; called by muse, mutect2, varscan2
- MAN1B1 | c.*406G>C | 3'UTR (SNP) | VAF 28/80 reads (35%) | called by muse, mutect2
- MAP4K4 | c.2396+41C>G | Intron (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- MAP6 | c.1316+2702C>G | Intron (SNP) | VAF 4/92 reads (4%) | catalogued as rs1003435792; called by muse, mutect2
- MAP6 | c.1316+2351C>G | Intron (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- MAPK10 | c.311+134C>T | Intron (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2
- MAPK12 | c.426+43C>A | Intron (SNP) | VAF 37/100 reads (37%) | called by muse, mutect2, varscan2
- MARK2 | c.-414G>A | 5'UTR (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- MAST4 | c.674+17119C>G | Intron (SNP) | VAF 7/107 reads (7%) | called by muse, mutect2
- MBL1P | n.123C>T | RNA (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- MBLAC2 | c.*1039C>A | 3'UTR (SNP) | VAF 26/84 reads (31%) | called by muse, varscan2
- MC4R | c.*112G>C | 3'UTR (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- MCC | c.-536G>A | 5'UTR (SNP) | VAF 35/96 reads (36%) | catalogued as rs893824697; called by muse, mutect2, varscan2
- MCMDC2 | c.*855G>T | 3'UTR (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- MECP2 | c.*8104G>C | 3'UTR (SNP) | VAF 37/46 reads (80%) | called by muse, mutect2, varscan2
- MEMO1 | c.62-19792G>A | Intron (SNP) | VAF 32/108 reads (30%) | called by muse, mutect2, varscan2
- MFAP5 | c.*226C>T | 3'UTR (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- MFSD11 | chr17:76737238 C>G | 5'Flank (SNP) | VAF 10/32 reads (31%) | catalogued as rs1245136006; called by mutect2, varscan2
- MIA2 | c.*800G>A | 3'UTR (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- MIR365B | n.28G>A | RNA (SNP) | VAF 30/165 reads (18%) | catalogued as rs753933844; called by muse, mutect2, varscan2
- MIR495 | n.43T>C | RNA (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- MOB4 | chr2:197515622 C>T | 5'Flank (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- MOGS | c.352+63G>C | Intron (SNP) | VAF 35/80 reads (44%) | called by muse, mutect2, varscan2
- MRPL50 | c.*1097C>T | 3'UTR (SNP) | VAF 57/168 reads (34%) | called by muse, mutect2, varscan2
- MRPS35 | chr12:27710733 C>G | 5'Flank (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2
- MRS2 | c.*1299G>A | 3'UTR (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- MST1L | n.112G>C | RNA (SNP) | VAF 13/167 reads (8%) | catalogued as rs778106909; called by muse, mutect2
- MTHFR | c.*617C>G | 3'UTR (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- MUC3A | c.*383C>G | 3'UTR (SNP) | VAF 12/327 reads (4%) | catalogued as rs1215249753; called by muse, mutect2
- MYH16 | n.4025G>A | RNA (SNP) | VAF 10/38 reads (26%) | catalogued as rs999891692; called by muse, mutect2, varscan2
- MYL1 | c.-26T>C | 5'UTR (SNP) | VAF 37/98 reads (38%) | called by muse, mutect2, varscan2
- NAA40 | c.*2077C>T | 3'UTR (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- NAA40 | c.*2563G>A | 3'UTR (SNP) | VAF 4/32 reads (13%) | catalogued as rs940554452; called by muse, mutect2
- NAGK | chr2:71068473 G>A | 5'Flank (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- NAGK | c.*77C>T | 3'UTR (SNP) | VAF 12/191 reads (6%) | called by muse, mutect2
- NAP1L5 | c.-24G>C | 5'UTR (SNP) | VAF 11/55 reads (20%) | catalogued as rs371680899; called by muse, mutect2, varscan2
- NAPA | c.667-48G>A | Intron (SNP) | VAF 26/61 reads (43%) | catalogued as rs1183664654; called by muse, mutect2, varscan2
- NCAPH2 | c.861+25G>A | Intron (SNP) | VAF 24/49 reads (49%) | called by muse, varscan2
- NDST1 | c.*3736G>A | 3'UTR (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- NDUFA5 | c.*3533G>T | 3'UTR (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- NDUFS3 | c.381+109G>A | Intron (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- NEBL | c.684+526C>T | Intron (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2, varscan2
- NEDD4L | c.49-16445G>A | Intron (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- NEK4 | c.*1028C>T | 3'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- NEK4 | c.*905G>C | 3'UTR (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- NF1 | c.7870-9T>G | Intron (SNP) | VAF 44/96 reads (46%) | called by muse, mutect2, varscan2
- NFASC | c.*4095G>A | 3'UTR (SNP) | VAF 25/108 reads (23%) | called by muse, mutect2, varscan2
- NHLH2 | c.*634G>A | 3'UTR (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- NKD1 | c.-2G>A | 5'UTR (SNP) | VAF 15/33 reads (45%) | catalogued as rs1173034043; called by muse, mutect2, varscan2
- NME4 | c.*168C>T | 3'UTR (SNP) | VAF 31/83 reads (37%) | catalogued as COSV99556801; called by muse, varscan2
- NODAL | c.*254G>A | 3'UTR (SNP) | VAF 30/77 reads (39%) | called by muse, mutect2, varscan2
- NPEPPS | c.-92C>G | 5'UTR (SNP) | VAF 2/7 reads (29%) | catalogued as rs1409396879; called by muse, mutect2
- NPR3 | c.*2916C>T | 3'UTR (SNP) | VAF 11/47 reads (23%) | catalogued as COSV99423713; called by muse, mutect2, varscan2
- NRBP2 | c.*1296C>T | 3'UTR (SNP) | VAF 26/56 reads (46%) | catalogued as rs966022251; called by muse, mutect2, varscan2
- NRM | c.*249C>T | 3'UTR (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- NSD2 | c.*665G>A | 3'UTR (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- NTRK3 | c.*9242G>A | 3'UTR (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- NTRK3 | chr15:87875469 C>G | 3'Flank (SNP) | VAF 6/50 reads (12%) | called by mutect2, varscan2
- NUDT21 | c.*1824C>T | 3'UTR (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2, varscan2
- NUDT21 | c.*573C>T | 3'UTR (SNP) | VAF 26/86 reads (30%) | called by muse, mutect2, varscan2
- NXPH3 | c.*3114C>T | 3'UTR (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- OR51E1 | c.*628C>T | 3'UTR (SNP) | VAF 9/101 reads (9%) | called by muse, mutect2
- OR51E2 | c.*231G>C | 3'UTR (SNP) | VAF 38/75 reads (51%) | called by muse, mutect2, varscan2
- OSBPL9 | c.1909-77C>T | Intron (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- PACSIN2 | c.*793C>A | 3'UTR (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- PALLD | c.1965-12650G>A | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- PANK3 | c.*5434A>C | 3'UTR (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- PCDH7 | c.-874G>A | 5'UTR (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- PCDH7 | c.-555G>A | 5'UTR (SNP) | VAF 14/99 reads (14%) | called by muse, varscan2
- PCMTD1 | c.*2007T>G | 3'UTR (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- PDIA3 | c.167+162G>A | Intron (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- PDLIM4 | c.670+85C>T | Intron (SNP) | VAF 53/126 reads (42%) | catalogued as rs1017431672, COSV53804263; called by muse, mutect2, varscan2
- PDZD8 | c.*974G>A | 3'UTR (SNP) | VAF 5/127 reads (4%) | called by muse, mutect2
- PFKFB2 | c.*252C>G | 3'UTR (SNP) | VAF 19/89 reads (21%) | catalogued as rs984961081; called by muse, mutect2, varscan2
- PGM3 | c.*413G>A | 3'UTR (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- PGM3 | c.*78G>C | 3'UTR (SNP) | VAF 35/74 reads (47%) | called by muse, mutect2, varscan2
- PHF14 | c.*311G>A | 3'UTR (SNP) | VAF 11/43 reads (26%) | called by mutect2, varscan2
- PIFO | c.*630G>A | 3'UTR (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2
- PIGP | c.*134G>C | 3'UTR (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- PIPSL | n.300G>C | RNA (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- PLAAT3 | c.*471del | 3'UTR (DEL) | VAF 6/54 reads (11%) | called by pindel, varscan2
- PLEKHA7 | c.2008-43C>G | Intron (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- PLPP4 | c.*235G>A | 3'UTR (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- PLPP6 | c.*1007C>T | 3'UTR (SNP) | VAF 8/60 reads (13%) | called by mutect2, varscan2
- PPIG | c.*925C>T | 3'UTR (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- PPP1R15B | c.-159C>T | 5'UTR (SNP) | VAF 11/177 reads (6%) | catalogued as rs535999861, COSV100916386; called by muse, mutect2
- PPP2CA | c.*1121C>G | 3'UTR (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- PRSS22 | c.83-124C>T | Intron (SNP) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- PRTG | c.*4858G>A | 3'UTR (SNP) | VAF 15/47 reads (32%) | catalogued as rs1054805717; called by muse, mutect2, varscan2
- PRUNE1 | c.*1198C>G | 3'UTR (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- PRUNE1 | c.*1318C>T | 3'UTR (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- PRUNE2 | c.*265C>G | 3'UTR (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- PSMC5 | c.24+169C>T | Intron (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2
- PSMD11 | c.*1-12C>G | Intron (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- PSMD11 | c.*93C>T | 3'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- PTGS1 | c.*507G>C | 3'UTR (SNP) | VAF 35/80 reads (44%) | called by muse, mutect2, varscan2
- PTPN20 | chr10:47000953 C>T | 3'Flank (SNP) | VAF 12/220 reads (5%) | called by muse, mutect2
- PUM2 | c.*1441G>C | 3'UTR (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- PUS1 | c.-383C>T | 5'UTR (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- RARA | c.179-5510C>T | Intron (SNP) | VAF 40/97 reads (41%) | called by muse, mutect2, varscan2
- RASSF6 | c.*572C>T | 3'UTR (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- RAX | c.*1097G>A | 3'UTR (SNP) | VAF 41/119 reads (34%) | called by muse, mutect2, varscan2
- RBBP4 | c.16+196G>A | Intron (SNP) | VAF 5/11 reads (45%) | catalogued as rs996740113, COSV59385556; called by muse, mutect2, varscan2
- RCOR3 | c.*745G>A | 3'UTR (SNP) | VAF 8/70 reads (11%) | called by mutect2, varscan2
- RCSD1 | c.*1055C>G | 3'UTR (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- REXO1 | c.-30C>G | 5'UTR (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- RGMA | c.15-761G>A | Intron (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- RGPD1 | chr2:86903878 C>T | 5'Flank (SNP) | VAF 20/63 reads (32%) | catalogued as rs775668723; called by muse, mutect2, varscan2
- RHOT2 | c.*559C>T | 3'UTR (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- RHPN1 | c.*943C>G | 3'UTR (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- RNASEK | c.195+347G>A | Intron (SNP) | VAF 6/13 reads (46%) | catalogued as rs1037657033; called by muse, varscan2
- RNF31 | c.-27G>A | 5'UTR (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- ROBO4 | c.2435+60C>T | Intron (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- RPL37 | c.3+140G>C | Intron (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- RPS3 | chr11:75405121 C>T | 3'Flank (SNP) | VAF 8/37 reads (22%) | catalogued as rs912132655; called by muse, mutect2, varscan2
- RRAGD | c.-251G>A | 5'UTR (SNP) | VAF 23/67 reads (34%) | catalogued as rs1314657270; called by muse, mutect2, varscan2
- RTN3 | chr11:63681461 C>T | 5'Flank (SNP) | VAF 15/27 reads (56%) | called by muse, mutect2, varscan2
- RUSC1 | chr1:155320789 C>G | 5'Flank (SNP) | VAF 9/156 reads (6%) | called by muse, mutect2
- RXRB | c.1349-70C>T | Intron (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2
- SAMD5 | c.*1997G>A | 3'UTR (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- SART3 | c.*412G>A | 3'UTR (SNP) | VAF 32/91 reads (35%) | called by muse, mutect2, varscan2
- SAV1 | chr14:50632429 C>T | 3'Flank (SNP) | VAF 29/67 reads (43%) | catalogued as rs1011888583; called by muse, mutect2, varscan2
- SCART1 | c.*161C>G | 3'UTR (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- SCRN2 | c.1-48C>T | Intron (SNP) | VAF 12/32 reads (38%) | catalogued as rs1302118976; called by muse, mutect2, varscan2
- SDR16C5 | chr8:56300969 G>C | 3'Flank (SNP) | VAF 28/97 reads (29%) | called by muse, varscan2
- SEC61A1 | c.-38G>C | 5'UTR (SNP) | VAF 15/44 reads (34%) | catalogued as rs1456002740; called by muse, mutect2
- SECISBP2L | c.*1091G>A | 3'UTR (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
- SECISBP2L | c.-63G>A | 5'UTR (SNP) | VAF 20/66 reads (30%) | catalogued as rs1027196542; called by muse, mutect2, varscan2
- SELENOI | chr2:26346108 G>A | 5'Flank (SNP) | VAF 34/88 reads (39%) | catalogued as rs376678544; called by muse, mutect2, varscan2
- SELL | c.*310C>T | 3'UTR (SNP) | VAF 36/120 reads (30%) | called by muse, varscan2
- SEMA4A | c.*510C>T | 3'UTR (SNP) | VAF 10/126 reads (8%) | catalogued as rs946902747; called by muse, mutect2
- SH3BP5 | c.-20C>T | 5'UTR (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2
- SHISA9 | c.-19G>C | 5'UTR (SNP) | VAF 6/16 reads (38%) | catalogued as rs964671969; called by muse, mutect2
- SIGLEC6 | c.*493C>T | 3'UTR (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- SIRPB2 | c.860-470C>G | Intron (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2
- SIX4 | c.*3617G>A | 3'UTR (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- SIX4 | c.*1539G>C | 3'UTR (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- SKIL | c.*426G>A | 3'UTR (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- SLC22A13 | c.*951G>A | 3'UTR (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2
- SLC22A2 | c.*295C>T | 3'UTR (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- SLC22A3 | c.*926C>G | 3'UTR (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- SLC25A36 | c.385+2094G>A | Intron (SNP) | VAF 22/54 reads (41%) | called by mutect2, varscan2
- SLC25A36 | c.386-38C>T | Intron (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- SLC2A13 | c.1034+308G>A | Intron (SNP) | VAF 46/98 reads (47%) | called by muse, mutect2, varscan2
- SLC35C2 | c.*668C>T | 3'UTR (SNP) | VAF 20/69 reads (29%) | called by muse, mutect2, varscan2
- SLC37A4 | c.984+111C>T | Intron (SNP) | VAF 30/51 reads (59%) | called by muse, mutect2, varscan2
- SLC4A8 | c.1248+186C>T | Intron (SNP) | VAF 13/51 reads (25%) | catalogued as rs1402511191; called by muse, mutect2, varscan2
- SLC7A2 | c.-22-4484G>C | Intron (SNP) | VAF 10/304 reads (3%) | called by muse, mutect2
- SLCO4C1 | c.*1875G>A | 3'UTR (SNP) | VAF 15/306 reads (5%) | called by muse, mutect2
- SLIT3 | c.1459+9G>A | Intron (SNP) | VAF 11/39 reads (28%) | catalogued as rs1265231718; called by muse, mutect2, varscan2
- SMC4 | chr3:160399837 G>A | 5'Flank (SNP) | VAF 30/108 reads (28%) | catalogued as rs868759380; called by muse, mutect2, varscan2
- SMC6 | c.*1146T>G | 3'UTR (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- SNORC | c.74-309C>G | Intron (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- SNORD114-28 | n.7G>T | RNA (SNP) | VAF 36/106 reads (34%) | called by muse, mutect2, varscan2
- SORL1 | c.*3160G>A | 3'UTR (SNP) | VAF 5/63 reads (8%) | catalogued as rs1039142494; called by muse, mutect2
- SOX11 | c.*3833G>A | 3'UTR (SNP) | VAF 28/64 reads (44%) | called by muse, varscan2
- SOX21 | c.*767G>A | 3'UTR (SNP) | VAF 31/43 reads (72%) | called by muse, mutect2, varscan2
- SOX3 | c.*455G>C | 3'UTR (SNP) | VAF 31/42 reads (74%) | called by muse, mutect2, varscan2
- SP1 | c.*4055C>G | 3'UTR (SNP) | VAF 32/94 reads (34%) | called by muse, mutect2, varscan2
- SPICE1 | c.*2003C>G | 3'UTR (SNP) | VAF 23/65 reads (35%) | catalogued as rs990697119; called by muse, mutect2, varscan2
- SPN | c.*4300C>T | 3'UTR (SNP) | VAF 13/37 reads (35%) | catalogued as rs1219553310; called by muse, mutect2, varscan2
- SPRED1 | c.*3151C>G | 3'UTR (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- SRPK1 | c.*1272G>C | 3'UTR (SNP) | VAF 14/62 reads (23%) | called by mutect2, varscan2
- SRPX | c.-36G>A | 5'UTR (SNP) | VAF 7/41 reads (17%) | catalogued as rs1279449199; called by muse, mutect2, varscan2
- SRSF5 | c.-82C>T | 5'UTR (SNP) | VAF 10/19 reads (53%) | catalogued as rs764363876, COSV67937067; called by muse, mutect2
- SSPOP | n.3957G>A | RNA (SNP) | VAF 20/52 reads (38%) | catalogued as rs372778854; called by muse, mutect2, varscan2
- ST6GAL1 | c.*871G>A | 3'UTR (SNP) | VAF 27/73 reads (37%) | called by muse, varscan2
- ST6GAL1 | c.*1939G>A | 3'UTR (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- ST6GALNAC4 | c.*254C>T | 3'UTR (SNP) | VAF 25/64 reads (39%) | called by mutect2, varscan2
- STAB1 | c.4761+29C>G | Intron (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- STON1 | c.*1306C>T | 3'UTR (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- STX1A | c.209-63G>A | Intron (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- SUSD6 | c.*2595G>A | 3'UTR (SNP) | VAF 19/34 reads (56%) | called by muse, mutect2, varscan2
- SYS1 | c.*1201C>T | 3'UTR (SNP) | VAF 19/67 reads (28%) | catalogued as rs915187214; called by muse, mutect2, varscan2
- SYT10 | c.*1089G>A | 3'UTR (SNP) | VAF 19/54 reads (35%) | catalogued as rs1356490360; called by muse, mutect2, varscan2
- TACC1 | c.162-143C>T | Intron (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- TACC3 | c.2062+99G>A | Intron (SNP) | VAF 29/64 reads (45%) | called by muse, mutect2, varscan2
- TBC1D5 | c.*1691G>C | 3'UTR (SNP) | VAF 8/36 reads (22%) | called by mutect2, varscan2
- TBC1D9B | c.*1162C>T | 3'UTR (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- TCAIM | c.165+1333C>T | Intron (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- TCAIM | c.*474C>T | 3'UTR (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- TCTN3 | c.*570C>G | 3'UTR (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
- TFAM | c.*3338G>C | 3'UTR (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- THY1 | c.37+175G>A | Intron (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
60 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 60 other) are not listed here.
